Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABIZ, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABIZ-TTP2-A (Primary Tumor).

SPECIMEN(S) RECEIVED:

- A) Right lung neoplasm, needle aspirate
- B) Right lung, upper lobe
- C) Paratracheal lymph nodes from station 4R

GROSS EXAMINATION:

- A) 0.5 cc of reddish material
- B) Lobe of lung measuring 19x16x6, almost completely filled with grayish-white neoplasm measuring 16 cm in greatest diameter, extensively necrotic, located 1 cm from the bronchial margin. Remainder of pulmonary parenchyma appears congested. Opaque visceral pleura. Five peribronchial lymph nodes isolated.
- C) Eight anthracotic lymph nodes, the largest measuring 2 cm.

DIAGNOSIS:

- A) Positive for malignant tumor cells.
- B) Poorly differentiated (G3) adenocarcinoma of the lung, extensively necrotic. No evidence of peritumoral neoplastic vascular invasion.
Visceral pleura and bronchial margins of surgical resection free of neoplasia.
Vascular congestion in remainder of pulmonary parenchyma.
- A-C) Nonspecific reactive lymph node inflammation with sinus histiocytosis and anthracosis in 13/13 lymph nodes.

Histopathologic staging:

pT2 N0

Intraoperative examination:

- A) Positive for malignant tumor cells

CDDP-YP-ABIZ-01-PR

ICD-0-3

adenocarcinoma, NOS 8140/3
Site: @ lung, upper lobe C34.1

ICD-10

C34.11

Source: NCI Genomic Data Commons file 67fffc61-c5f4-490e-b67f-536b4ba0bafc (CDDP-ABIZ-TTP2.91437058-DBA6-498F-BC1C-F59A33B12251.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).